TCGA case TCGA-XQ-A8TA — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: University of Sao Paulo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b47791ba-85fd-41d0-ac1f-b6fa06f18e96

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Brazil; Age at index: 59 years; Vital status: Dead; Days to death: 146 days; Cause of death: Cancer Related; Cause of death source: Medical Record.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 59.9 years (21,889 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC clinical T: T3a; AJCC clinical M: M1b; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Gleason score: 10.
   Pathology details: Consistent pathology review: Yes; Zone of origin prostate: Peripheral zone.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Day -10 (initial diagnosis): Days to imaging: -10 days; Imaging type: MRI; Imaging findings: Distant Metastasis.
- Days to follow up: 146 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Biochemical.
- Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: Distant Metastasis; Timepoint: Initial Diagnosis.
- Imaging type: Bone Scan, NOS; Imaging result: Positive; Timepoint: Initial Diagnosis.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 323 ng/mL (day 62).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XQ-A8TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-XQ-A8TA-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XQ-A8TA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XQ-A8TA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: Yes, Pharmaceutical Treatment Prior to Resection; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Transurethral resection (TURBT); Bone scan results: Prostate Cancer Metastases Present [cM1b]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: Yes; Cause of death: Prostate Cancer; Biochemical recurrence indicator: Yes; New tumor event diagnosis indicator: No.
- Diagnostic ct abd pelvis results: Ct scan ab pelvis results: Distant Metastasis [e.g. cM1].
- Diagnostic mri results: Mri results: Distant Metastasis [e.g. cM1].
- Stage record, Psa: PSA most recent results: 323.0.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 5.
- New tumor event: Progression after hormone treatment: Yes; Progression after hormone treatment type: Distant Metastases.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Prostate Cancer; New tumor event diagnosis indicator: No; Progression after hormone treatment: Yes.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: During Enrollment, TSS confirmed patient received pharmaceutical treatment prior to TCGA tumor procurement. No other information given.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 146 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 146 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 146 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XQ-A8TA-01A-11D-A363-01): tumor purity 0.97, ploidy 1.94, whole-genome doublings 0.
